Gene-level copy-number profile of tumor specimen TCGA-ET-A40P-01A from TCGA case TCGA-ET-A40P, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 32.4 years (11,843 days).
Specimen TCGA-ET-A40P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.0f6608b3-ca2f-4ddb-b515-1e89e0eeb58c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ET-A40P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0eaa4c04-bf90-427b-b6c8-d25b0e1de418

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,390; copy number 2: 58,394; copy number 3: 32; copy number 4: 1; copy number 5: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ET-A40P-01A-11D-A23L-01): tumor purity 0.75, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:155,491,336–155,493,598, 1 gene, copy number 5: AC008725.1.
- chr19:27,638,483–27,646,483, 2 genes, copy number 5: ERVK-28, AC112702.1.

Autosomal genes at a single copy (total copy number 1): 1,382. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
